Surgical pathology report (de-identified scan), TCGA case TCGA-Q9-A6FW, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Emory University, specimen TCGA-Q9-A6FW-01A (Primary Tumor).

[page 1 of 4]
-Confidential Document

This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

Document Type: Anat Path Reports
Document Date:
Document Status:
Document Title: Histology
Performed By:
Verified By:
Encounter info:

* Final Report *

ICD-O-3
Adenocarcinoma NOS
8140/3
C64F Distal Third of esophagus
path Gastroesophageal junction
C16.0

Patient Name:

MRN:

Location:

Client:

Submitting

Phys:

Copy To Phys:

DOB:

Gender:

M

Acc #:

(Age:

Collected:

Received:

Reported:

Final Surgical Pathology Report

Final Pathologic Diagnosis

- A. DISTAL TWO-THIRDS ESOPHAGUS AND PROXIMAL ONE-THIRD STOMACH, PARTIAL ESOPHAGOGASTRECTOMY, A1FS:
- INVASIVE ADENOCARCINOMA, MODERATELY TO POORLY DIFFERENTIATED (5.0 X 2.8 X 1.4 CM).
- TUMOR EXTENDS TRANSMURALLY INTO PERI-ESOPHAGEAL AND PERI-GASTRIC SOFT TISSUES.
- ARISING IN A BACKGROUND OF INTESTINAL METAPLASIA AND HIGH-GRADE DYSPLASIA AT THE GASTROESOPHAGEAL JUNCTION.
- EXTENSIVE PERINEURAL INVASION AND LYMPHOVASCULAR INVASION ARE PRESENT.
- CIRCUMFERENTIAL MARGIN IS POSITIVE FOR ADENOCARCINOMA.
- PROXIMAL ESOPHAGEAL AND DISTAL GASTRIC MARGINS ARE NEGATIVE FOR DYSPLASIA OR CARCINOMA.
- THREE OF TWENTY-TWO LYMPH NODES POSITIVE FOR METASTATIC ADENOCARCINOMA, WITH EXTRANODAL EXTENSION (3/22).
- SYNOPTIC REPORT.
- B. LYMPH NODES, RIGHT LEVEL 8, EXCISION:
- TWELVE LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/12).

Printed by:

Printed on:

Page 1 of 4
(Continued)

IHPAC Discrepancy		
Dual/Synchronous Tumor Noted		
Case is (c/cle)		

W 2/11/13
5/21/13

[page 2 of 4]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

C. LYMPH NODES, 4R, EXCISION:

- EIGHTEEN LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/18).

D. LYMPH NODES, LEVEL 7, EXCISION:

- TEN LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/10).

Electronically Signed by

Assisted by:

Synoptic Worksheet

A. Distal two-thirds of esophagus with proximal one-third of stomach:

Specimen:	Esophagus
	Proximal stomach
Procedure:	Esophagogastrectomy
Tumor Site:	Esophagogastric junction (EGJ)
Relationship of Tumor to Esophagogastric Junction:	Tumor midpoint is located at the esophagogastric junction
Distance of tumor center from esophagogastric junction:	0 cm
Tumor Size:	Greatest dimension: 5.0 cm
	Additional dimension: 2.8 cm
	Additional dimension: 1.4 cm
Histologic Type:	Adenocarcinoma
Histologic Grade:	G2: Moderately differentiated
Microscopic Tumor Extension:	Tumor invades through the muscularis propria into the periesophageal soft tissue (adventitia)
Margins:	Proximal margin uninvolved by invasive carcinoma
	Proximal margin uninvolved by dysplasia
	Distal margin uninvolved by invasive carcinoma
	Distal margin uninvolved by dysplasia
	Circumferential (adventitial) margin or Deep margin involved by invasive carcinoma
Treatment Effect:	No prior treatment
Lymph-Vascular Invasion:	Present
Perineural Invasion:	Present
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT3: Tumor invades adventitia
Regional Lymph Nodes (pN):	pN2: 3 to 6 nodes involved
	Number of regional lymph nodes examined: 62

Printed by:

Printed on:

[page 3 of 4]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

Distant Metastasis (pM):	Number of regional lymph nodes involved: 3
Additional Pathologic Findings:	Not applicable
	Intestinal metaplasia (Barrett's esophagus)
	Dysplasia, high grade

Clinical History

Esophageal cancer. Esophagogastrectomy, jejunostomy tube.

Specimen(s) Received

A: Distal two-thirds of esophagus with proximal one-third of stomach
B: Level 8 lymph node, right
C: 4R lymph nodes
D: 7 lymph nodes

Gross Description

Specimen A is received fresh, labeled with the patient's name and medical record number as "distal two-thirds of esophagus with proximal one-third of stomach." The specimen consists of one portion of esophagus measuring 12.0 cm in length and 3.5 cm in diameter with attached stomach measuring 12.0 x 4.0 x 3.0 cm. There is a firm area at the GE junction with mucosal ulceration and wall thickening. The area of palpable wall firmness measures 5.0 x 2.8 x 1.4 cm, and the area of ulceration measures 2.5 x 2.5 cm. These areas are 5.8 cm from the proximal margin and 2.3 cm from the distal margin. There are two foci of mucosal ulceration, 1 cm proximal to the main ulcer. Otherwise, the specimen is unremarkable. Several possible lymph nodes are identified. The radial margin is inked black. Sections are submitted as follows: Dictated by Dr. _

Specimen B is received fresh, labeled with the patient's name and medical record number as "right level 8 lymph node." The specimen consists of multiple fragments of nodal tissue that measure 3.5 x 2.4 x 0.8 cm, in aggregate. The specimen is submitted entirely in cassettes "B1" through "B3." (Dictated by Dr. _

Specimen C is received fresh, labeled with the patient's name and medical record number as "4R lymph node." The specimen consists of multiple fragments of nodal tissue admixed with fat that measure 5.5 x 3.0 x 2.0 cm, in aggregate. Several fragments of lymph nodes, as well as whole lymph nodes are identified. Possible nodal fragments are submitted in cassettes "C1" and "C2" while presumed whole lymph nodes are submitted in cassettes "C3" and "C4." (Dictated by Dr. _

Specimen D is received fresh, labeled with the patient's name and medical record number as "#7 lymph node." The specimen consists of several fragments of nodal tissue that measure 4.3 x 3.6 x 1.3 cm, in aggregate. The largest of these fragment measures 2.4 x 2.2 x 1.0 cm. Sections are submitted as follows. (Dictated by Dr. _

CASSETTE SUMMARY:

A1FS:	Proximal margin
A2:	Representative distal margin
A3-A6:	Lesion, GE junction
A7:	Lesion, within stomach, one lymph node bisected

Printed by:
Printed on:

[page 4 of 4]
Confidential Document

This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

regarding

Anat Path Reports

* Final Report *

A8: Lesion, within stomach
A9: Representative esophagus and stomach, uninvolved
A10: Satellite areas of superficial mucosal ulceration, esophagus
A11-A15: Possible lymph nodes, whole
D1,2: Largest fragment, bisected
D3: Second largest fragment
D4: Fragmented possible lymph nodes
D5: Possible lymph nodes, whole

Intraoperative Consult Diagnosis

A1FS: ESOPHAGUS, PROXIMAL MARGIN (FROZEN SECTION): NEGATIVE FOR IN SITU OR INVASIVE CARCINOMA.
Frozen section results were communicated to the surgical team and were repeated back by Dr.

Pathologist:

Microscopic Description

Microscopic examination performed.

Printed by:
Printed on:

Source: NCI Genomic Data Commons file 920a5343-cda4-43d6-9852-a0ed5b03ce99 (TCGA-Q9-A6FW.80F41C8A-BB4C-41D3-B4A4-6EAC6C36482F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).